TCGA case TCGA-FG-6691 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e4d9b696-3311-44e7-9191-fde56c080a00

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 23 years; Vital status: Alive.

Diagnoses (2)
1. Astrocytoma, NOS (the primary disease): ICD-O-3 morphology code: 9400/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 23.0 years (8,403 days); Year of diagnosis: 2011; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,257 days (3.4 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Temporal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,020 days (2.8 years); Days to treatment end: 1,058 days (2.9 years); Treatment dose: 45 Gy; Treatment outcome: Stable Disease; Number of fractions: 25; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 1,135 days (3.1 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: Antiseizure Treatment, preoperative; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.
2. Recurrence of diagnosis 1 (Astrocytoma, NOS). Age at diagnosis: 25.5 years (9,316 days); Days to diagnosis: 913 days (2.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 984 days (2.7 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (7 entries)
- Day -9 (preoperative): Karnofsky performance status: 100.
- Day 103 (adjuvant therapy): Disease response: Tumor Free; Karnofsky performance status: 90.
- Day 235 (adjuvant therapy): Karnofsky performance status: 80.
- Days to follow up: 382 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 729 days (2.0 years); Disease response: Tumor Free.
- Day 913 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 913 days (2.5 years).
- Days to follow up: 1,257 days (3.4 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FG-6691-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-FG-6691-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-FG-6691-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-FG-6691-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FG-6691-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; History ionizing radiation to head: No; Tumor status: Tumor free; Tumor site: Supratentorial, Temporal Lobe; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: No; Family history brain tumor: No; Idh1 mutation test indicator: No; Inherited genetic syndrome indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: Temodar.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 4: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,257 days; disease-specific survival: no event (censored), 1,257 days; disease-free interval: event (new tumor event after initially disease-free), 913 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 913 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FG-6691-01A-11D-1892-01): tumor purity 0.83, ploidy 2.1, whole-genome doublings 0.
